Somatic mutation profile of tumor specimen C3L-02137-54 (aliquot CPT0201080002) from CPTAC case C3L-02137, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 56.6 years (20,688 days).
Specimen C3L-02137-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0e002e6-4cac-41d0-8187-65c5f166ebb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02137-50 (Buccal Cell Normal), aliquot CPT0201120003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69c50cd8-e5de-4e41-97e1-6cfaa60f6b00

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 4, Frame Shift Ins 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 76/250 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- COL3A1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1186071837, COSV58595248; called by muse, mutect2
- HGSNAT | c.1209G>C p.W403C | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as CM065268, CM1111505; called by muse, mutect2, varscan2
- KMT2D | c.6010C>T p.Q2004* | Nonsense Mutation (SNP) | VAF 34/293 reads (12%) | catalogued as CM105463, COSV56463089; called by muse, mutect2, varscan2
- KRTAP5-5 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV68785716; called by muse, varscan2
- POR | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782644829; called by muse, mutect2, varscan2
- SIPA1L2 | c.4805C>T p.T1602M | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as rs774023610; called by muse, mutect2, varscan2
- STAG2 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 60/149 reads (40%) | catalogued as COSV54356717, COSV54365939, COSV54376336; called by muse, mutect2, varscan2
- SYT16 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760675924, COSV70855812; called by muse, varscan2
- ZNF99 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1197598646, COSV101233750; called by muse, mutect2, varscan2
- ATP10B | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- BIRC6 | c.5126T>A p.L1709H | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C12orf4 | c.1091A>C p.Q364P | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CBY3 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ERCC6L2 | c.2516dup p.N839Kfs*15 | Frame Shift Ins (INS) | VAF 29/105 reads (28%) | called by mutect2, pindel, varscan2
- MAPK8IP3 | c.3390C>G p.Y1130* | Nonsense Mutation (SNP) | VAF 102/225 reads (45%) | called by muse, mutect2, varscan2
- OR5D13 | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- PCDH11X | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 262/602 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SETD2 | c.5245G>T p.E1749* | Nonsense Mutation (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2, varscan2
- WT1 | c.1318dup p.Q440Pfs*3 | Frame Shift Ins (INS) | VAF 112/281 reads (40%) | called by mutect2, varscan2
- ZNF454 | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- IFNK | c.315T>C p.Y105= | Silent (SNP) | VAF 91/189 reads (48%) | catalogued as rs746556552; called by muse, mutect2, varscan2
- KIF2B | c.1959C>T p.T653= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as rs561814751; called by muse, mutect2, varscan2
- PAQR3 | c.714C>G p.P238= | Silent (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
- RGS6 | c.978C>T p.S326= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as COSV100666373; called by mutect2, varscan2
- VMA21 | c.30C>T p.N10= | Silent (SNP) | VAF 116/321 reads (36%) | catalogued as rs985172619; called by muse, mutect2, varscan2
- GOSR1 | c.348+12G>A | Intron (SNP) | VAF 24/335 reads (7%) | called by muse, mutect2
- ZNF513 | c.-29G>T | 5'UTR (SNP) | VAF 18/191 reads (9%) | called by muse, mutect2
